Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WO, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WO-01A (Primary Tumor).

Gross:

Ovoid encapsulated right adrenal tumor: weight 83 g, 65x60x45 mm, on cut dark red with pseudocystic cavities from which flows out blood.

Micro:

Solidly alveolarly shaped pheochromocytoma with extensive hemorrhagic necroses, with adrenal cortex rests on the periphery. Focal cytologic atypias in the tumor.

Staining for S100 protein – positive sustentacular cells and nervous fibers. Staining for chromogranin positive in pheochromocytoma cells, negative in adrenal cortex rests. Alfa inhibin negative in pheochromocytoma cells, positive in adrenal cortex remnants. MIB 1 <1% of positive nuclei.

PASS:

Large nests or diffuse growth (>10% of tumor volume)

Central (middle of large nests) or confluent tumor necrosis 2

High cellularity

Cellular monotony

Tumor cell spindling (even if focal)

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism

Nuclear hyperchromasia 1

Total 3

Procurement date:

Confirmation date:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site Adrenal gland NOS
C74.9
9/10/13

Source: NCI Genomic Data Commons file 50c09e98-164a-44d8-8f85-ad2e192075c1 (TCGA-S7-A7WO.89349C53-3BBF-4C7C-8ECA-934C6ABA530B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).